Somatic mutation profile of tumor specimen 0DW6BN from CCDI case PBCLZE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.8 years (5,409 days).
Specimen 0DW6BN: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 212600d0-97d0-422f-9710-6bafdc31bc45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW6AY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/273d365b-ca9e-433b-b58c-5d8853231ab3

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP2 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV62248397; called by muse, mutect2
- PFDN1 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 59/530 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs753965486, COSV55834384; called by muse, mutect2, varscan2
- RBMXL3 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 173/419 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.068); catalogued as rs199745174, COSV57759091; called by muse, mutect2, varscan2
- APPL2 | c.868A>C p.T290P | Missense Mutation (SNP) | VAF 136/373 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIGK | c.1105G>C p.G369R | Missense Mutation (SNP) | VAF 198/494 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2
- H6PD | c.543C>T p.F181= | Silent (SNP) | VAF 84/902 reads (9%) | catalogued as rs375431974, COSV66231876; called by muse, mutect2
- ITGB1BP2 | c.816+83A>C | Intron (SNP) | VAF 50/130 reads (38%) | called by muse, mutect2, varscan2
